Surgical pathology report (de-identified scan), TCGA case TCGA-2H-A9GI, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Erasmus MC, specimen TCGA-2H-A9GI-01A (Primary Tumor).

Pathology Report

Coded sample ID:

Date of tumor procurement:

Date of report:

Histologic diagnosis: moderate differentiated adenocarcinoma in Barrett-epithelium

Anatomic site with laterality: distal esophagus

Tumor size: 4x3,5 cm

Lymph node status: 8 lymph nodes, of which 4 contains tumor

Any comments or amendments: radical resection

ICD-O-3

Adenocarcinoma NOS 8140/3

Site: Esophagus distal third C15.

On 1/29/14

Source: NCI Genomic Data Commons file ed91881f-86b1-4542-8bae-fade0e68d39a (TCGA-2H-A9GI.339C5A0E-F816-4403-BFE6-4FBC13803C09.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).